MMRF case MMRF_2452 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9232adfb-7715-45aa-b274-0f53518e65f5

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.4 years (23,508 days); ISS stage: I; Days to last known disease status: 732 days (2.0 years); Days to last follow up: 732 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 193 days; Days to treatment end: 193 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.066 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 365 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.211 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 9.86 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 7.75 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.53 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L; C-Reactive Protein 0.14 mg/dL.
- Day 84 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 80.3 mg/dL; Immunoglobulin G 3.04 g/L; Immunoglobulin A 0.498 g/L; Immunoglobulin M 0.243 g/L; Beta 2 Microglobulin 2.11 µg/mL; Lactate Dehydrogenase 4.62 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.76 ×10⁹/L; Absolute Neutrophil 2.98 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 76.9 µmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 12.2 mmol/L.
- Day 171 (ECOG 0): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 49.1 mg/dL; Immunoglobulin G 3.99 g/L; Immunoglobulin A 0.734 g/L; Immunoglobulin M 0.335 g/L; Beta 2 Microglobulin 2.07 µg/mL; Lactate Dehydrogenase 4.23 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 13.4 ×10⁹/L; Absolute Neutrophil 11.3 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 67.2 µmol/L; Calcium 2.15 mmol/L; Glucose 6.22 mmol/L.
- Day 266 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.6 mg/dL; Immunoglobulin G 5.6 g/L; Immunoglobulin A 0.511 g/L; Immunoglobulin M 0.235 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 58.3 µmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 7.43 mmol/L.
- Day 375 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.3 mg/dL; Immunoglobulin G 5.33 g/L; Immunoglobulin A 0.409 g/L; Immunoglobulin M 0.283 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.53 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 61.9 µmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 7.81 mmol/L.
- Day 469 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 3.49 g/L; Beta 2 Microglobulin 2.67 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.88 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 532 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.4 mg/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 0.904 g/L; Immunoglobulin M 1.65 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.42 ×10⁹/L; Absolute Neutrophil 3.43 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.45 mmol/L; Albumin 46.8 g/L; Total Protein 6.8 g/dL; Glucose 6.44 mmol/L.
- Day 648 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 8.86 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 1.5 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.95 ×10⁹/L; Absolute Neutrophil 4.63 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 104 µmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 6 mmol/L.
- Day 732 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.4 mg/dL; Immunoglobulin G 7.6 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 1.1 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.99 ×10⁹/L; Absolute Neutrophil 3.17 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 118 µmol/L; Calcium 2.45 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 6.33 mmol/L.

Other clinical attributes
- Day 1: Weight: 73 kg; Height: 167 cm.

Biospecimens (2 samples)
- Sample MMRF_2452_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2452_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
